Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3584, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3584-01A (Primary Tumor).

Diagnosis:

Resection material from rectum with non-inflamed diverticula in the proximal section, tumor-free oral and aboral resection margins and inclusion of a locally advanced, ulcerated, moderately differentiated adenocarcinoma extending to within 2 mm of the perirectal resection margin and with deep infiltration of the perimuscular fatty tissue, with lymph and blood vessel inclusions and with numerous regional lymph node metastases (G2, pT3 L1 V1 locally R0 pN2 20/34).

Source: NCI Genomic Data Commons file 55eebb03-6dd6-4b2f-a8bc-cd8004af6f7b (TCGA-AG-3584.C3822AFB-5B28-439C-A2BC-B3EEA955E4A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).